Somatic mutation profile of tumor specimen TARGET-10-PARDFN-09A (aliquot TARGET-10-PARDFN-09A-01D) from TARGET case TARGET-10-PARDFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,981 days).
Specimen TARGET-10-PARDFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff69768f-159a-4321-8efb-d96312c8c2b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDFN-10A (Blood Derived Normal), aliquot TARGET-10-PARDFN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/409cfb0e-b6c9-4d27-b58a-37e70d908421

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 2, 5'UTR 2, Splice Region 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1482C>T p.N494= | Splice Region (SNP) | VAF 22/72 reads (31%) | catalogued as rs751105630, COSV61272719, COSV61282847; called by muse, mutect2, varscan2
- ARNT2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs369899179; called by muse, mutect2, varscan2
- CLEC12A | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV58562690; called by muse, mutect2
- PAX5 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63914517; called by muse, mutect2, varscan2
- PKP2 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as rs200715477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCP10L2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs781709258, COSV52091315; called by muse, mutect2, varscan2
- UNC5C | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771070280, COSV104437809; called by muse, mutect2, varscan2
- ADGRD2 | c.2560A>C p.T854P | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLEC12A | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FAM13A | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- IGHV1-69D | c.351_352insCCC | In Frame Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel*, varscan2*
- RTF1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABCB1 | c.495G>A p.V165= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- CCDC17 | c.916T>C p.L306= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs1468651093; called by muse, mutect2, varscan2
- CDH7 | c.483A>G p.G161= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs1333760401; called by muse, mutect2, varscan2
- HERC2 | c.987C>T p.S329= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs773073050, COSV55320846; called by muse, mutect2
- PARP4 | c.4965C>T p.D1655= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs775387437; called by muse, mutect2, varscan2
- XIRP2 | c.10086C>A p.S3362= (on ENST00000628543; = p.S3537= on NM_152381.6) | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- CCSER1 | c.1932+13824C>T | Intron (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- FMO6P | n.906-3216C>T | Intron (SNP) | VAF 6/112 reads (5%) | catalogued as rs903713020; called by muse, mutect2
- IGHV1-69 | chr14:106714683 ins GGG | 3'Flank (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel*
- TCIM | c.-1G>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs764565156; called by muse, mutect2
- TNFRSF1A | c.-207C>A | 5'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs551199963; called by muse, varscan2
